Somatic mutation profile of tumor specimen TCGA-WA-A7GZ-01A (aliquot TCGA-WA-A7GZ-01A-11D-A34J-08) from TCGA case TCGA-WA-A7GZ, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Floor of mouth, NOS; Tumor grade: G2; Age at diagnosis: 58.1 years (21,207 days).
Specimen TCGA-WA-A7GZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c008810b-cdb5-48ca-b34e-07dcc1f34762.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WA-A7GZ-10A (Blood Derived Normal), aliquot TCGA-WA-A7GZ-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/43c772b7-3a86-468e-823e-3cc0e8bc0764

The open-access MAF lists 220 somatic variants for this specimen: 161 protein-altering or splice-affecting, 52 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 140, Silent 52, Nonsense Mutation 12, RNA 4, Frame Shift Del 3, In Frame Del 3, Splice Site 1, Intron 1, 5'Flank 1, 5'UTR 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.578A>C p.H193P | Missense Mutation (SNP) | VAF 30/66 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.13884C>A p.C4628* | Nonsense Mutation (SNP) | VAF 8/45 reads (18%) | catalogued as COSV101291253, COSV101291380; called by muse, mutect2, varscan2
- ACSM4 | c.1021C>T p.R341W | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs755148242, COSV68067243; called by muse, mutect2, varscan2
- AHNAK | c.8393C>G p.S2798* | Nonsense Mutation (SNP) | VAF 30/360 reads (8%) | catalogued as COSV99948421; called by muse, mutect2
- AHNAK2 | c.14090C>T p.S4697L | Missense Mutation (SNP) | VAF 48/85 reads (56%) | SIFT tolerated (0.33); PolyPhen benign (0.415); catalogued as rs377637525; called by muse, mutect2, varscan2
- ALDOB | c.616A>C p.T206P | Missense Mutation (SNP) | VAF 42/65 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs1311298251, COSV100878892; called by muse, mutect2, varscan2
- ANKRD6 | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs569364324, COSV60238758; called by muse, mutect2, varscan2
- ARFGEF2 | c.2374A>G p.M792V | Missense Mutation (SNP) | VAF 65/133 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV100904354; called by muse, mutect2, varscan2
- ARHGEF9 | c.614G>A p.C205Y | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99492072; called by muse, mutect2, varscan2
- ARID1B | c.4123G>A p.E1375K | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as rs1199179337, COSV99034269; called by muse, mutect2, varscan2
- ATP2B3 | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99685136; called by muse, mutect2, varscan2
- ATP8B4 | c.1601T>A p.F534Y | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV99466474; called by muse, mutect2, varscan2
- ATXN3 | c.968C>T p.S323L | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as rs1166934623, COSV100515457; called by muse, mutect2, varscan2
- B4GAT1 | c.1113G>T p.L371F | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100240331; called by muse, mutect2, varscan2
- C8orf76 | c.389C>T p.T130I | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99415135; called by muse, mutect2, varscan2
- CACNA1F | c.4890G>C p.E1630D | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100545086; called by muse, mutect2, varscan2
- CACNG7 | c.269C>T p.T90M | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs764997446, COSV99712133; called by muse, mutect2, varscan2
- CCDC141 | c.3076G>T p.E1026* | Nonsense Mutation (SNP) | VAF 27/102 reads (26%) | catalogued as rs139365189, COSV99837084; called by muse, mutect2, varscan2
- CERKL | c.1091G>C p.R364P (on ENST00000339098 / NM_001030311.2; = p.R338P on NM_201548.5) | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100183890, COSV59213652; called by muse, mutect2, varscan2
- CFH | c.3530A>G p.Y1177C | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as CM136980, COSV100809858; called by muse, mutect2, varscan2
- CKAP2 | c.952A>G p.I318V (on ENST00000378037 / NM_001098525.2; = p.I317V on NM_018204.5) | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT tolerated (0.75); PolyPhen benign (0.08); catalogued as rs752317658, COSV99318375; called by muse, mutect2, varscan2
- COMMD5 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1420187633, COSV100295984; called by muse, mutect2, varscan2
- CORO2B | c.832T>C p.Y278H | Missense Mutation (SNP) | VAF 60/224 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99963489; called by muse, mutect2, varscan2
- CPSF6 | c.421A>G p.M141V | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99879526; called by muse, mutect2, varscan2
- CRB1 | c.3296C>A p.T1099K | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as CM1111051, COSV66334867; called by muse, mutect2, varscan2
- CRYBG1 | c.4201G>T p.D1401Y | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV64812732; called by muse, mutect2, varscan2
- CYP7B1 | c.1117G>C p.E373Q | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs1484043098, COSV100042314; called by muse, mutect2
- DAO | c.412A>C p.I138L | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.78); PolyPhen benign (0.013); catalogued as COSV57322393; called by muse, mutect2, varscan2
- DERL2 | c.76C>G p.L26V | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.259); catalogued as COSV99342393; called by muse, mutect2, varscan2
- DNAJC10 | c.916A>T p.I306F | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as COSV99899433; called by muse, mutect2, varscan2
- DOCK4 | c.5789C>T p.A1930V | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.335); catalogued as rs776452844, COSV70236558; called by mutect2, varscan2
- DPP3 | c.1219G>A p.V407M | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1452287363, COSV100855651; called by muse, mutect2, varscan2
- DUSP16 | c.1877G>C p.R626T | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99963249; called by muse, mutect2
- EXO5 | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56416008, COSV99591354; called by muse, mutect2, varscan2
- FANCC | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as COSV100002700, COSV56658247; called by muse, varscan2
- FAT3 | c.5415C>A p.S1805R | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.94); PolyPhen benign (0.01); catalogued as COSV99967836; called by muse, mutect2, varscan2
- FBLN5 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as rs759434738, COSV99969745; called by muse, mutect2, varscan2
- FBXO11 | c.1342C>T p.R448W (on ENST00000403359 / NM_001190274.2; = p.R364W on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs749297387, COSV100319691; called by muse, mutect2, varscan2
- FLG | c.11291C>G p.S3764* | Nonsense Mutation (SNP) | VAF 206/611 reads (34%) | catalogued as rs1262578796, COSV100911798; called by muse, mutect2, varscan2
- FMN1 | c.3754C>T p.P1252S (on ENST00000616417 / NM_001277313.2; = p.P1029S on NM_001103184.4) | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.913); catalogued as COSV100569018; called by muse, mutect2, varscan2
- FMN2 | c.4207T>C p.Y1403H | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV100146161; called by muse, mutect2, varscan2
- FNBP4 | c.1289G>T p.G430V | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99771811; called by muse, mutect2, varscan2
- GCSAML | c.33C>G p.C11W | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100825995; called by muse, mutect2, varscan2
- GDPD5 | c.1411C>T p.P471S | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV100409388; called by muse, mutect2, varscan2
- GFM2 | c.499G>C p.D167H | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99714515; called by muse, mutect2, varscan2
- GFPT2 | c.163C>T p.Q55* | Nonsense Mutation (SNP) | VAF 17/311 reads (5%) | catalogued as COSV99517863; called by muse, mutect2
- GRIP2 | c.2018G>A p.S673N (on ENST00000619221; = p.S576N on NM_001080423.4) | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs1420749700, COSV99817494; called by muse, mutect2, varscan2
- GRM3 | c.955G>A p.G319S | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV100862181; called by muse, mutect2, varscan2
- GTDC1 | c.1084G>A p.D362N | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99601109; called by muse, mutect2, varscan2
- GTSE1 | c.1678C>T p.P560S | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.8); PolyPhen benign (0.074); catalogued as rs1311586740, COSV101483229, COSV101483249; called by muse, mutect2, varscan2
- H2BC11 | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 55/167 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV100345763, COSV100345829; called by muse, mutect2, varscan2
- HEATR9 | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.459); catalogued as rs1568310826; called by muse, mutect2, varscan2
- HELB | c.3237C>G p.F1079L | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as COSV56074974; called by muse, mutect2, varscan2
- HUNK | c.1060A>T p.K354* | Nonsense Mutation (SNP) | VAF 43/147 reads (29%) | catalogued as COSV99528682; called by muse, mutect2, varscan2
- IBSP | c.886G>C p.E296Q | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99883670; called by muse, mutect2, varscan2
- IDE | c.1771A>G p.N591D | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.254); catalogued as COSV99794149; called by muse, mutect2, varscan2
- ITGAE | c.2616G>C p.L872F | Missense Mutation (SNP) | VAF 83/260 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.939); catalogued as rs759183137, COSV99561237; called by muse, mutect2, varscan2
- KCNH4 | c.1873G>C p.E625Q | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.105); catalogued as COSV99237538; called by muse, mutect2, varscan2
- KDM2A | c.495C>G p.F165L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101284615, COSV101284661; called by muse, mutect2
- KDM3A | c.800A>G p.N267S | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1364218181, COSV100460675, COSV99072474; called by muse, mutect2, varscan2
- KHDRBS2 | c.560G>C p.G187A | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV99835339; called by muse, mutect2, varscan2
- KIAA1109 | c.9530G>A p.R3177K | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99167330; called by muse, mutect2, varscan2
- KIF2B | c.1429G>A p.A477T | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV99275737; called by muse, mutect2, varscan2
- KNDC1 | c.1627G>A p.V543I | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs182563365; called by muse, mutect2, varscan2
- LNX2 | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780629112, COSV100310796; called by muse, mutect2, varscan2
- LOXL2 | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV101207948; called by muse, mutect2, varscan2
- LRP2 | c.9754G>C p.E3252Q | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.996); catalogued as COSV55560883; called by muse, mutect2, varscan2
- LRP2 | c.9551G>C p.R3184P | Missense Mutation (SNP) | VAF 62/217 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99789410; called by muse, mutect2, varscan2
- LRRN3 | c.568C>G p.L190V | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as COSV100067482, COSV57817821; called by muse, mutect2, varscan2
- LRRN3 | c.1864G>A p.E622K | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100071793, COSV57817627; called by muse, mutect2, varscan2
- MERTK | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.265); catalogued as rs953052713, COSV54928951; called by muse, mutect2, varscan2
- MFSD12 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.716); catalogued as rs375464453; called by muse, mutect2
- MGAM | c.173G>A p.G58D | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV101516470; called by muse, mutect2
- MISP | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as COSV53119219, COSV53119497; called by muse, mutect2, varscan2
- MMEL1 | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56518059; called by muse, mutect2, varscan2
- MROH8 | c.1943C>T p.A648V | Missense Mutation (SNP) | VAF 43/336 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); catalogued as rs779325533, COSV99457557; called by muse, mutect2, varscan2
- MTERF2 | c.191G>T p.R64I | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99526878; called by muse, mutect2
- MUC5AC | c.14627A>G p.E4876G | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV100611510; called by muse, mutect2, varscan2
- NBEAL1 | c.4072G>C p.E1358Q | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.134); catalogued as COSV101495741; called by muse, mutect2
- NCBP1 | c.362A>G p.Y121C | Missense Mutation (SNP) | VAF 88/155 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs201055450, COSV100912635; called by muse, mutect2, varscan2
- NDUFA9 | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.044); catalogued as rs863224085, COSV99865815; ClinVar: likely benign; called by muse, mutect2, varscan2
- NEK1 | c.2695G>C p.E899Q | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101455744; called by muse, mutect2, varscan2
- NEU1 | c.1216G>A p.V406M | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs767633589, COSV99999074; called by muse, mutect2, varscan2
- NFU1 | c.739G>A p.D247N (on ENST00000410022 / NM_001002755.4; = p.D223N on NM_015700.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/195 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV100361276; called by muse, mutect2
- NLRP7 | c.2110T>G p.C704G (on ENST00000340844 / NM_206828.3; = p.C676G on NM_139176.3) | Missense Mutation (SNP) | VAF 110/340 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.328); catalogued as COSV100052998; called by muse, mutect2, varscan2
- NMRK2 | c.504C>T p.V168= | Splice Region (SNP) | VAF 27/70 reads (39%) | catalogued as COSV99396184, COSV99396407; called by muse, mutect2, varscan2
- NOLC1 | c.811T>A p.S271T | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100893704; called by muse, mutect2, varscan2
- NPFFR2 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV100440970; called by muse, mutect2, varscan2
- NPHS2 | c.263G>T p.R88L | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as COSV100858189; called by muse, mutect2, varscan2
- NTSR1 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 64/155 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs140186245, COSV65138382; called by muse, mutect2, varscan2
- OGDH | c.2617G>C p.D873H | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV56049389; called by muse, mutect2, varscan2
- OR5D16 | c.660T>A p.Y220* | Nonsense Mutation (SNP) | VAF 18/164 reads (11%) | catalogued as COSV101004054; called by muse, mutect2
- OR5L1 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.491); catalogued as COSV100450122, COSV61734383; called by muse, mutect2, varscan2
- OR5M10 | c.64G>C p.V22L | Missense Mutation (SNP) | VAF 52/139 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV101595908; called by muse, mutect2, varscan2
- PCDHGA8 | c.943T>C p.Y315H | Missense Mutation (SNP) | VAF 51/128 reads (40%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.651); catalogued as rs1236685113, COSV99542021; called by muse, mutect2, varscan2
- PHKG1 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV99818290; called by muse, mutect2, varscan2
- PLEC | c.11371G>C p.E3791Q (on ENST00000322810 / NM_201380.4; = p.E3681Q on NM_000445.5) | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.072); catalogued as COSV100516074, COSV59621802; called by muse, mutect2, varscan2
- PNCK | c.197G>A p.R66H (on ENST00000340888 / NM_001366975.1; = p.R149H on NM_001039582.3) | Missense Mutation (SNP) | VAF 93/122 reads (76%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs782395857, COSV61744122; called by muse, mutect2, varscan2
- POLE | c.5411A>G p.K1804R | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100267406; called by muse, mutect2, varscan2
- POLR1A | c.4103A>G p.N1368S | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs781468536, COSV99808047; called by muse, mutect2, varscan2
- POLR2B | c.356C>G p.T119R | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100108028, COSV100108182; called by muse, mutect2, varscan2
- PRKCG | c.1529C>T p.T510M | Missense Mutation (SNP) | VAF 161/471 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99669263; called by muse, mutect2, varscan2
- RAB3A | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 52/197 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs367923648; called by muse, mutect2, varscan2
- RETREG3 | c.1093G>C p.E365Q | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV99519004; called by muse, mutect2, varscan2
- RING1 | c.1093A>T p.I365F | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100761807; called by muse, mutect2, varscan2
- RIOK2 | c.1066C>T p.R356W | Missense Mutation (SNP) | VAF 50/145 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1161416386, COSV51611853; called by muse, mutect2, varscan2
- RNF41 | c.927A>G p.I309M | Missense Mutation (SNP) | VAF 42/217 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100560257; called by muse, mutect2, varscan2
- SAPCD2 | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.197); catalogued as rs777563126, COSV101294046; called by muse, mutect2, varscan2
- SEC23IP | c.2965C>T p.R989* | Nonsense Mutation (SNP) | VAF 9/68 reads (13%) | catalogued as rs904414734, COSV64830651; called by muse, mutect2, varscan2
- SEC31A | c.193T>C p.S65P | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV100307768; called by muse, mutect2, varscan2
- SLC13A3 | c.896T>A p.F299Y | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.088); catalogued as COSV99286908; called by muse, mutect2, varscan2
- SLC35G3 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 51/199 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.137); catalogued as rs766443809, COSV52010812; called by muse, mutect2, varscan2
- SMARCA4 | c.1615C>T p.R539C | Missense Mutation (SNP) | VAF 46/179 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60790749; called by muse, mutect2, varscan2
- SNPH | c.659A>G p.D220G | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV100378277; called by muse, mutect2, varscan2
- SP1 | c.2301C>G p.I767M (on ENST00000327443 / NM_138473.3; = p.I760M on NM_003109.1) | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.724); catalogued as COSV100540742; called by muse, mutect2, varscan2
- SPATA31D1 | c.3107A>T p.K1036I | Missense Mutation (SNP) | VAF 34/195 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100782902; called by muse, mutect2, varscan2
- SPTBN5 | c.3900G>T p.Q1300H | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV100311813; called by muse, mutect2, varscan2
- SUPT20H | c.1549A>G p.M517V (on ENST00000350612 / NM_001014286.3; = p.M518V on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.037); catalogued as rs768762893, COSV100634753; called by muse, mutect2, varscan2
- TBC1D16 | c.1589C>G p.S530C | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV100188208, COSV99077063; called by muse, mutect2, varscan2
- THADA | c.1570G>C p.E524Q | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.145); catalogued as COSV100367932, COSV100369057; called by muse, mutect2, varscan2
- THSD7A | c.4243T>A p.C1415S | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1257465897, COSV101439772; called by muse, mutect2, varscan2
- THSD7B | c.2922T>A p.N974K | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.272); catalogued as COSV99754212; called by muse, mutect2, varscan2
- TLN1 | c.1409C>T p.P470L | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as rs148182997; called by muse, mutect2, varscan2
- TMC4 | c.376C>T p.R126W (on ENST00000617472 / NM_001145303.3; = p.R120W on NM_144686.4) | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs758987586, COSV55475203; called by muse, mutect2, varscan2
- TMPRSS6 | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.641); catalogued as COSV100695972, COSV60981069; called by muse, mutect2
- TNFRSF21 | c.1030T>C p.F344L | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99729936; called by muse, mutect2, varscan2
- TNKS1BP1 | c.4603C>T p.Q1535* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as COSV100836133; called by muse, mutect2, varscan2
- TOGARAM1 | c.2877C>G p.F959L | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs757956482, COSV100818142, COSV63890736; called by muse, mutect2, varscan2
- TRANK1 | c.7130G>T p.R2377M | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV100083707; called by muse, mutect2, varscan2
- TRIM32 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV100528830; called by muse, mutect2
- TRPS1 | c.15G>C p.K5N (on ENST00000220888 / NM_001330599.2; = p.K18N on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV55238603, COSV55248629, COSV99632296; called by muse, mutect2, varscan2
- UBA6 | c.1065G>C p.L355F | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.408); catalogued as COSV100451784; called by muse, mutect2
- UNC13A | c.4603G>C p.E1535Q | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV53192661, COSV99408865; called by muse, mutect2, varscan2
- USP17L2 | c.1563C>A p.H521Q | Missense Mutation (SNP) | VAF 39/194 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0.011); catalogued as COSV100414601, COSV100414652; called by muse, varscan2
- UTRN | c.3860G>A p.R1287H | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs373769853; called by muse, mutect2, varscan2
- WASHC2C | c.107C>A p.S36* | Nonsense Mutation (SNP) | VAF 3/27 reads (11%) | catalogued as rs1165620299, COSV100314106; called by muse, mutect2
- WASHC2C | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 38/240 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.238); catalogued as rs1253480411, COSV100314107; called by muse, varscan2
- WDR59 | c.1237G>C p.D413H | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.219); catalogued as COSV100049521; called by muse, mutect2, varscan2
- XKR5 | c.91G>T p.G31* | Nonsense Mutation (SNP) | VAF 11/21 reads (52%) | catalogued as COSV101306713; called by muse, mutect2, varscan2
- ZBTB41 | c.2635C>G p.L879V | Missense Mutation (SNP) | VAF 31/185 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.563); catalogued as rs1302536010, COSV100963267; called by muse, mutect2, varscan2
- ZC3H14 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs950260962, COSV99193134; called by muse, mutect2, varscan2
- ZNF264 | c.187A>T p.I63F | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV99567330; called by muse, mutect2, varscan2
- ZNF483 | c.577G>T p.E193* | Nonsense Mutation (SNP) | VAF 17/152 reads (11%) | catalogued as COSV100493025; called by muse, mutect2, varscan2
- ZNF551 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 67/222 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.945); catalogued as COSV99990097; called by muse, mutect2, varscan2
- ZNF583 | c.1007G>T p.G336V | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.927); catalogued as COSV99382218; called by muse, mutect2, varscan2
- ZNF804B | c.1685A>G p.N562S | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1246199993, COSV100304694; called by muse, mutect2, varscan2
- ZNFX1 | c.2467A>T p.I823L | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.107); catalogued as COSV100870940; called by muse, mutect2, varscan2
- ZSWIM4 | c.1123G>C p.E375Q | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as COSV54319906, COSV99585103, COSV99585340; called by muse, mutect2, varscan2
- ZWILCH | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100328787; called by muse, mutect2, varscan2
- AHNAK | c.10803_10817del p.V3605_K3609del | In Frame Del (DEL) | VAF 91/458 reads (20%) | called by mutect2, pindel, varscan2
- CEP126 | c.2753_2759del p.Y918Lfs*2 | Frame Shift Del (DEL) | VAF 63/212 reads (30%) | called by mutect2, pindel, varscan2
- CIBAR2 | c.187_201del p.E63_T67del | In Frame Del (DEL) | VAF 12/63 reads (19%) | called by mutect2, pindel, varscan2
- COL6A6 | c.5430del p.R1810Sfs*88 | Frame Shift Del (DEL) | VAF 5/22 reads (23%) | called by mutect2, pindel, varscan2
- FAT1 | c.11573_11590del p.R3858_S3863del | In Frame Del (DEL) | VAF 10/41 reads (24%) | called by mutect2, pindel, varscan2
- KIR3DL3 | c.25G>T p.A9S | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.953); called by muse, mutect2
- NAALADL2 | c.527_537del p.D176Vfs*10 | Frame Shift Del (DEL) | VAF 29/161 reads (18%) | called by mutect2, pindel, varscan2
- PIGG | c.2905T>A p.C969S (on ENST00000453061 / NM_001127178.3; = p.C961S on NM_017733.4) | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- SETD2 | c.4840-4_4841del p.X1614_splice | Splice Site (DEL) | VAF 29/100 reads (29%) | called by mutect2, pindel, varscan2
- SPAG7 | c.383dup p.D128Efs*6 | Frame Shift Ins (INS) | VAF 50/234 reads (21%) | called by mutect2, pindel, varscan2
- TAF15 | c.880C>T p.P294S (on ENST00000605844 / NM_139215.3; = p.P291S on NM_003487.4) | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.986); called by muse, mutect2
- ZNF605 | c.1127G>C p.R376T | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ACTR5 | c.1554G>T p.R518= | Silent (SNP) | VAF 64/154 reads (42%) | catalogued as COSV99710115; called by muse, mutect2, varscan2
- AHNAK | c.8613C>G p.L2871= | Silent (SNP) | VAF 28/371 reads (8%) | catalogued as rs753986334, COSV57225495; called by muse, mutect2
- ANK1 | c.3594C>T p.N1198= | Silent (SNP) | VAF 46/204 reads (23%) | catalogued as rs186020985; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARRDC2 | c.1080G>A p.P360= | Silent (SNP) | VAF 43/110 reads (39%) | catalogued as rs145370397; called by muse, mutect2, varscan2
- ATF4 | c.366C>G p.L122= | Silent (SNP) | VAF 20/288 reads (7%) | catalogued as rs767181464, COSV100307495; called by muse, mutect2
- BCL9 | c.795C>A p.P265= | Silent (SNP) | VAF 34/101 reads (34%) | catalogued as COSV99325485; called by muse, mutect2, varscan2
- CACNA1B | c.537T>C p.L179= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as COSV99498455; called by muse, mutect2, varscan2
- CDR2 | c.1284G>A p.E428= | Silent (SNP) | VAF 41/113 reads (36%) | catalogued as rs529904009, COSV99193543; called by muse, mutect2, varscan2
- CHST1 | c.138G>T p.L46= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as COSV100346370, COSV57324346; called by muse, mutect2, varscan2
- CSK | c.1116C>T p.F372= | Silent (SNP) | VAF 41/176 reads (23%) | catalogued as rs375554302; called by muse, mutect2, varscan2
- CST5 | c.156C>T p.I52= | Silent (SNP) | VAF 63/325 reads (19%) | catalogued as rs202048792; called by muse, mutect2, varscan2
- EXOC6B | c.249G>A p.L83= | Silent (SNP) | VAF 26/238 reads (11%) | catalogued as COSV99725195; called by muse, mutect2, varscan2
- FAT4 | c.1377A>T p.A459= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV101272524; called by muse, mutect2
- FEZF1 | c.744C>T p.F248= | Silent (SNP) | VAF 56/136 reads (41%) | catalogued as rs922828804, COSV100484517; called by muse, mutect2, varscan2
- FNDC4 | c.30C>A p.P10= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs758790557, COSV99253963; called by muse, varscan2
- GNA14 | c.42G>A p.S14= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as COSV100503221; called by muse, mutect2, varscan2
- GRIK5 | c.366C>T p.P122= | Silent (SNP) | VAF 48/165 reads (29%) | catalogued as rs772036723, COSV53476686; called by muse, mutect2, varscan2
- GRM1 | c.3198C>T p.Y1066= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as rs575610612, COSV99267296; called by muse, mutect2, varscan2
- H1-1 | c.582G>A p.A194= | Silent (SNP) | VAF 18/234 reads (8%) | catalogued as rs1292627090, COSV99772128; called by muse, mutect2
- HCN1 | c.1464G>A p.L488= | Silent (SNP) | VAF 43/205 reads (21%) | catalogued as rs1414226989, COSV100301219; called by muse, mutect2, varscan2
- HIVEP3 | c.5184G>A p.A1728= | Silent (SNP) | VAF 33/244 reads (14%) | catalogued as rs781357885, COSV56012548; called by muse, mutect2, varscan2
- HMGCS2 | c.1428C>T p.F476= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV101024853; called by muse, mutect2, varscan2
- HRH1 | c.267C>G p.L89= | Silent (SNP) | VAF 25/153 reads (16%) | catalogued as COSV101229077; called by muse, mutect2, varscan2
- ITGB6 | c.1137A>G p.V379= | Silent (SNP) | VAF 42/144 reads (29%) | catalogued as COSV99324743; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1440G>A p.L480= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV100311812; called by muse, mutect2, varscan2
- KCNA7 | c.787C>A p.R263= | Silent (SNP) | VAF 34/113 reads (30%) | catalogued as rs140612328, COSV99671968; called by muse, mutect2, varscan2
- KDF1 | c.837C>T p.I279= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV57671000; called by muse, mutect2, varscan2
- KIAA0586 | c.531G>A p.P177= (on ENST00000619416 / NM_001244190.2; = p.P192= on NM_014749.5) | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs369143869; called by muse, mutect2, varscan2
- KIAA0753 | c.2364C>T p.Y788= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as COSV100810640; called by muse, mutect2, varscan2
- LIG4 | c.2487G>A p.L829= | Silent (SNP) | VAF 22/110 reads (20%) | catalogued as COSV100799978; called by muse, mutect2, varscan2
- NBEAL1 | c.7500C>T p.I2500= | Silent (SNP) | VAF 50/105 reads (48%) | catalogued as COSV101355565; called by muse, mutect2, varscan2
- OR10Q1 | c.633G>T p.V211= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV100372347; called by muse, mutect2, varscan2
- OR4D11 | c.903G>A p.L301= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as rs116174674, COSV57585210; called by muse, mutect2, varscan2
- OR9Q1 | c.75C>T p.L25= | Silent (SNP) | VAF 26/110 reads (24%) | catalogued as COSV100109436, COSV100110193; called by muse, mutect2, varscan2
- PAPOLG | c.555C>T p.D185= | Silent (SNP) | VAF 27/136 reads (20%) | catalogued as COSV99474889; called by muse, mutect2, varscan2
- PASK | c.3279C>T p.F1093= | Silent (SNP) | VAF 33/81 reads (41%) | catalogued as COSV99299834; called by muse, mutect2, varscan2
- PCDHGA1 | c.1794G>A p.S598= | Silent (SNP) | VAF 46/96 reads (48%) | catalogued as rs369957326, COSV100966011; called by muse, mutect2, varscan2
- PCED1A | c.411G>A p.V137= | Silent (SNP) | VAF 10/148 reads (7%) | catalogued as COSV100642910, COSV62314106; called by muse, mutect2
- PEG3 | c.1302C>G p.L434= | Silent (SNP) | VAF 53/179 reads (30%) | catalogued as COSV99689563; called by muse, mutect2, varscan2
- PLXNA1 | c.555C>G p.L185= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV99303570; called by muse, mutect2, varscan2
- PPP1R12C | c.507G>T p.L169= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV99670294; called by muse, mutect2, varscan2
- RPL10A | c.132G>A p.Q44= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as rs370449510; called by muse, mutect2, varscan2
- RYR3 | c.9180C>T p.A3060= (on ENST00000389232; = p.A3061= on NM_001036.6) | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV66801479; called by muse, mutect2, varscan2
- SHOC2 | c.1080C>G p.L360= | Silent (SNP) | VAF 6/106 reads (6%) | catalogued as COSV99510324; called by muse, mutect2
- SHQ1 | c.411A>G p.V137= | Silent (SNP) | VAF 38/90 reads (42%) | catalogued as rs746755221, COSV100345092; called by muse, mutect2, varscan2
- SLC25A36 | c.613C>T p.L205= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV100149159; called by muse, mutect2, varscan2
- SMTNL1 | c.930G>A p.Q310= (on ENST00000399154; = p.Q347= on NM_001105565.2) | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as rs759578981, COSV101216456; called by muse, mutect2, varscan2
- SPG11 | c.882A>G p.G294= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as rs753132861, COSV99969080; called by muse, mutect2, varscan2
- TET1 | c.6159C>T p.N2053= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as COSV65390186; called by muse, mutect2
- TNRC18 | c.3733C>T p.L1245= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV101269777; called by muse, mutect2, varscan2
- VNN2 | c.303A>T p.P101= | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as COSV100426865; called by muse, mutect2, varscan2
- ZNF99 | c.1272C>G p.P424= | Silent (SNP) | VAF 29/80 reads (36%) | catalogued as COSV101233882, COSV68055082; called by muse, varscan2
- AL136982.4 | n.569A>G | RNA (SNP) | VAF 123/355 reads (35%) | called by muse, mutect2, varscan2
- DCAF13 | chr8:103415110 G>A | 5'Flank (SNP) | VAF 22/73 reads (30%) | catalogued as rs780957947, COSV99884539; called by muse, mutect2, varscan2
- MEF2C | c.402+98C>T | Intron (SNP) | VAF 26/65 reads (40%) | catalogued as rs780541747, COSV60934042; called by muse, mutect2, varscan2
- NCAM1 | c.-161C>T | 5'UTR (SNP) | VAF 7/26 reads (27%) | catalogued as rs781791930, COSV101207504; called by muse, mutect2, varscan2
- OSGIN1 | n.765G>A | RNA (SNP) | VAF 26/75 reads (35%) | catalogued as COSV100652421; called by muse, mutect2, varscan2
- SNORD116-13 | n.42G>A | RNA (SNP) | VAF 55/218 reads (25%) | called by muse, mutect2, varscan2
- SNORD116-5 | n.65C>T | RNA (SNP) | VAF 14/388 reads (4%) | called by muse, mutect2
